Somatic mutation profile of tumor specimen 0DTB91 from CCDI case PBCJAB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 18.7 years (6,821 days).
Specimen 0DTB91: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2c6ba253-e17b-4f0d-9152-13776f15d274.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DTB8H (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bcd012e2-859a-4526-bdab-6a7ae22b4e29

The open-access MAF lists 15 somatic variants for this specimen: 10 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 4, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS18 | c.2671G>A p.G891R | Missense Mutation (SNP) | VAF 232/618 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BRINP3 | c.1204A>G p.T402A | Missense Mutation (SNP) | VAF 48/685 reads (7%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2
- CDCA7L | c.476A>G p.K159R | Missense Mutation (SNP) | VAF 368/1295 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CDON | c.2277A>C p.K759N | Missense Mutation (SNP) | VAF 133/694 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- CFH | c.2888T>A p.F963Y | Missense Mutation (SNP) | VAF 130/1468 reads (9%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.997); called by muse, mutect2
- EEF1AKMT4-ECE2 | c.2407G>T p.G803W | Missense Mutation (SNP) | VAF 60/402 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EPB41L2 | c.2900A>G p.D967G | Missense Mutation (SNP) | VAF 274/949 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM205A | c.3505C>T p.Q1169* | Nonsense Mutation (SNP) | VAF 43/550 reads (8%) | called by muse, mutect2
- HUS1B | c.344C>G p.A115G | Missense Mutation (SNP) | VAF 97/301 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.302); called by muse, mutect2, varscan2
- PSG1 | c.304T>A p.Y102N | Missense Mutation (SNP) | VAF 136/440 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- CELA3B | c.348G>A p.S116= | Silent (SNP) | VAF 80/213 reads (38%) | catalogued as rs771802321, COSV61405673; called by muse, mutect2, varscan2
- HCK | c.322C>T p.L108= | Silent (SNP) | VAF 100/536 reads (19%) | called by mutect2, varscan2
- TEX13A | c.885G>A p.Q295= | Silent (SNP) | VAF 156/421 reads (37%) | called by muse, mutect2, varscan2
- WDR49 | c.684A>G p.T228= (on ENST00000308378 / NM_001366158.1; = p.T569= on NM_001348951.2 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 70/1343 reads (5%) | catalogued as rs772013962; called by muse, mutect2
- KY | c.1090+171C>A | Intron (SNP) | VAF 48/706 reads (7%) | called by muse, mutect2
